Somatic mutation profile of tumor specimen C3L-01036-01 (aliquot CPT0123440006) from CPTAC case C3L-01036, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 64.2 years (23,457 days).
Specimen C3L-01036-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4cbdba72-5ca2-4950-826b-7d9ef4564b81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01036-31 (Blood Derived Normal), aliquot CPT0124820002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/748f8193-293c-466b-8cc7-1a0a4e2a87ee

The open-access MAF lists 85 somatic variants for this specimen: 44 protein-altering or splice-affecting, 28 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 28, Intron 7, Nonsense Mutation 3, In Frame Del 2, RNA 2, Splice Region 2, 5'Flank 2, Frame Shift Del 1, 5'UTR 1, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 25/347 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.375G>A p.T125= | Splice Region (SNP) | VAF 27/187 reads (14%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARHGEF18 | c.2434G>A p.A812T (on ENST00000359920 / NM_001130955.2; = p.A708T on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1359446974; called by muse, mutect2, varscan2
- CDC42BPG | c.2818G>A p.V940I | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs1200159529; called by muse, mutect2, varscan2
- CFAP47 | c.7844C>T p.T2615I | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.039); catalogued as rs967476751; called by muse, mutect2
- EIF4G3 | c.2624A>G p.H875R | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.056); catalogued as rs570848878; called by muse, mutect2, varscan2
- GRID1 | c.2146G>A p.G716R | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs779959152, COSV60038671; called by muse, mutect2, varscan2
- GTF3C1 | c.5588G>A p.R1863H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs370190480; called by muse, mutect2, varscan2
- HRH2 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 52/398 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as rs781393851; called by muse, mutect2, varscan2
- JAG2 | c.2332C>T p.R778W | Missense Mutation (SNP) | VAF 35/386 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1452922654; called by muse, mutect2
- JAK3 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.453); catalogued as rs201784993, COSV71686009; called by muse, mutect2, varscan2
- LAMA1 | c.3496G>A p.V1166M | Missense Mutation (SNP) | VAF 31/232 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs545607128, COSV67534155; called by muse, mutect2, varscan2
- LYST | c.11069C>T p.T3690M | Missense Mutation (SNP) | VAF 44/336 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1380931438, COSV67704269; called by muse, mutect2, varscan2
- MYO3A | c.4682G>A p.R1561Q | Missense Mutation (SNP) | VAF 39/341 reads (11%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs773690359, COSV56325431, COSV56342277; called by muse, mutect2, varscan2
- NFIC | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV59413275; called by muse, mutect2, varscan2
- PLEKHG4B | c.2141G>A p.R714H (on ENST00000283426; = p.R1070H on NM_052909.5) | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.027); catalogued as rs148131393; called by muse, mutect2, varscan2
- PLEKHM1 | c.48G>A p.P16= | Splice Region (SNP) | VAF 35/341 reads (10%) | catalogued as rs1459508370; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNA1 | c.4369G>T p.A1457S | Missense Mutation (SNP) | VAF 53/501 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52532961; called by muse, mutect2, varscan2
- PTPRM | c.4183C>T p.R1395C | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753091710, COSV59842875; called by muse, mutect2, varscan2
- SLC18A2 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs751675923, COSV53690884; called by muse, mutect2, varscan2
- USP2 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs765354693; called by muse, mutect2, varscan2
- WDR86 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs914805975; called by muse, mutect2, varscan2
- AZIN1 | c.500_502dup p.N167dup | In Frame Ins (INS) | VAF 27/246 reads (11%) | called by mutect2, pindel
- BEND4 | c.847T>C p.S283P | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- C19orf47 | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 39/269 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ENPEP | c.2840G>A p.R947K | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOSL2 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 68/450 reads (15%) | called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1001G>T p.R334L | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- KDM4E | c.595A>G p.N199D | Missense Mutation (SNP) | VAF 43/453 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KMT2C | c.1438A>T p.K480* | Nonsense Mutation (SNP) | VAF 13/122 reads (11%) | called by muse, mutect2, varscan2
- LONP2 | c.218T>A p.L73Q | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); called by muse, mutect2
- MARK2 | c.1613_1614dup p.H539Cfs*78 (on ENST00000402010 / NM_001039469.2; = p.H505Cfs*78 on NM_017490.4) | Frame Shift Ins (INS) | VAF 23/223 reads (10%) | called by mutect2, pindel
- MYO9B | c.3241C>T p.Q1081* | Nonsense Mutation (SNP) | VAF 40/392 reads (10%) | called by muse, mutect2, varscan2
- NCKAP1 | c.2788_2829del p.Y930_K943del | In Frame Del (DEL) | VAF 18/144 reads (13%) | called by mutect2, pindel
- NF1 | c.7752T>G p.I2584M (on ENST00000358273 / NM_001042492.3; = p.I2563M on NM_000267.3) | Missense Mutation (SNP) | VAF 42/327 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- NTF3 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); called by muse, mutect2
- PDZRN4 | c.1100G>T p.S367I (on ENST00000402685 / NM_001164595.2; = p.S109I on NM_013377.4) | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.981); called by muse, mutect2
- RIMBP2 | c.3137_3139del p.K1046del | In Frame Del (DEL) | VAF 14/96 reads (15%) | called by pindel, varscan2
- SAMD9 | c.3461A>T p.D1154V | Missense Mutation (SNP) | VAF 51/504 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SP3 | c.2260_2275del p.S754Kfs*76 | Frame Shift Del (DEL) | VAF 19/161 reads (12%) | called by mutect2, pindel
- STAG2 | c.3140C>A p.S1047Y | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLE4 | c.1319C>A p.T440K | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.044); called by muse, mutect2
- ZNF567 | c.788G>T p.C263F (on ENST00000536254 / NM_001322913.1; = p.C232F on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- ZNF695 | c.1274A>G p.Q425R | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.038); called by muse, mutect2
- AC138647.1 | c.522G>A p.T174= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as rs928558505; called by muse, mutect2
- ADAMTS14 | c.924C>T p.L308= | Silent (SNP) | VAF 33/332 reads (10%) | catalogued as rs143037838, COSV100941847; called by muse, mutect2
- ADCY5 | c.78C>T p.P26= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- BSN | c.2436C>T p.H812= | Silent (SNP) | VAF 19/139 reads (14%) | catalogued as rs754219572, COSV56521041; called by muse, mutect2, varscan2
- C4orf19 | c.603T>C p.H201= | Silent (SNP) | VAF 24/236 reads (10%) | called by muse, mutect2
- CALU | c.255C>T p.D85= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as rs770954063; called by muse, mutect2, varscan2
- CFAP46 | c.159A>C p.A53= | Silent (SNP) | VAF 9/161 reads (6%) | catalogued as rs1162984584; called by muse, mutect2
- CHRNB2 | c.879C>T p.D293= | Silent (SNP) | VAF 32/258 reads (12%) | catalogued as COSV100872621; called by muse, mutect2, varscan2
- COL5A1 | c.1239C>T p.D413= | Silent (SNP) | VAF 37/308 reads (12%) | catalogued as rs775974461; called by muse, mutect2, varscan2
- EPOP | c.813G>A p.G271= | Silent (SNP) | VAF 29/280 reads (10%) | catalogued as rs1322239937; called by muse, mutect2, varscan2
- FNIP1 | c.2055A>T p.G685= | Silent (SNP) | VAF 32/242 reads (13%) | called by muse, mutect2, varscan2
- GPX6 | c.654C>T p.F218= | Silent (SNP) | VAF 24/186 reads (13%) | catalogued as COSV62657244; called by muse, mutect2, varscan2
- HOXD1 | c.462C>T p.Y154= | Silent (SNP) | VAF 25/255 reads (10%) | catalogued as COSV100514176; called by muse, mutect2, varscan2
- IFIH1 | c.2166A>C p.I722= | Silent (SNP) | VAF 32/308 reads (10%) | called by muse, mutect2, varscan2
- INTS5 | c.2691G>A p.T897= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as rs1201907983; called by muse, mutect2
- LOXHD1 | c.2841C>T p.D947= | Silent (SNP) | VAF 82/579 reads (14%) | catalogued as rs761010290; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRRK2 | c.4323C>T p.R1441= | Silent (SNP) | VAF 43/420 reads (10%) | catalogued as rs112998035; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMRN2 | c.2049C>T p.D683= | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- NCAN | c.2751G>A p.P917= | Silent (SNP) | VAF 34/286 reads (12%) | catalogued as rs764591928, COSV53060225; called by muse, mutect2, varscan2
- NEUROD4 | c.936C>A p.S312= | Silent (SNP) | VAF 15/135 reads (11%) | catalogued as COSV54472848; called by muse, mutect2, varscan2
- PCDHB5 | c.1587C>T p.R529= | Silent (SNP) | VAF 106/709 reads (15%) | catalogued as rs781920885, COSV50660007; called by muse, mutect2, varscan2
- PDZRN3 | c.1866C>T p.N622= | Silent (SNP) | VAF 41/445 reads (9%) | catalogued as rs553747931, COSV55190281; called by muse, mutect2
- PRAMEF18 | c.714C>T p.F238= | Silent (SNP) | VAF 32/582 reads (5%) | catalogued as rs752123611; called by muse, mutect2
- SALL1 | c.2895G>A p.V965= | Silent (SNP) | VAF 66/536 reads (12%) | catalogued as rs1351117612; called by muse, mutect2, varscan2
- SLC25A51 | c.783G>C p.R261= | Silent (SNP) | VAF 28/385 reads (7%) | called by muse, mutect2
- TBX3 | c.1329G>A p.S443= (on ENST00000257566 / NM_016569.4; = p.S423= on NM_005996.4) | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as rs773964538, COSV57472125; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMEM132A | c.1698G>A p.T566= (on ENST00000453848 / NM_178031.3; = p.T567= on NM_017870.4) | Silent (SNP) | VAF 29/277 reads (10%) | catalogued as rs565546668; called by muse, mutect2, varscan2
- ZNF227 | c.1920C>T p.G640= | Silent (SNP) | VAF 16/126 reads (13%) | called by muse, mutect2, varscan2
- AC073648.1 | n.135C>T | RNA (SNP) | VAF 16/158 reads (10%) | catalogued as rs751580610; called by muse, mutect2, varscan2
- ADH1A | c.347+36G>A | Intron (SNP) | VAF 34/256 reads (13%) | catalogued as rs1238180863; called by muse, mutect2, varscan2
- CCDC136 | c.-132G>T | 5'UTR (SNP) | VAF 20/102 reads (20%) | called by muse, varscan2
- CLUL1 | chr18:613258 C>A | 5'Flank (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- EPB41L3 | chr18:5630430 G>A | 5'Flank (SNP) | VAF 61/538 reads (11%) | called by muse, mutect2, varscan2
- FBN2 | c.3344-48A>G | Intron (SNP) | VAF 10/238 reads (4%) | called by muse, mutect2
- GRIA4 | c.487+44689A>G | Intron (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- PIK3IP1 | c.308-23G>A | Intron (SNP) | VAF 6/64 reads (9%) | catalogued as rs1303048534; called by muse, mutect2
- RAB28 | c.391+831T>C | Intron (SNP) | VAF 6/112 reads (5%) | catalogued as rs1560140982; called by muse, mutect2
- REEP6 | c.517+161C>T | Intron (SNP) | VAF 21/175 reads (12%) | catalogued as rs747519860; called by muse, mutect2, varscan2
- TNFAIP2 | c.*609G>A | 3'UTR (SNP) | VAF 24/136 reads (18%) | catalogued as rs1164521202; called by muse, mutect2, varscan2
- TTC3P1 | n.5684A>T | RNA (SNP) | VAF 45/224 reads (20%) | called by muse, mutect2, varscan2
- ZEB2 | c.-69-14T>A | Intron (SNP) | VAF 13/332 reads (4%) | called by muse, mutect2
